TCGA case TCGA-SC-A6LM — Mesothelioma (TCGA-MESO)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e656cf38-2f5d-4306-90d9-ecb504d86351

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 64 years; Vital status: Dead; Days to death: 881 days (2.4 years).

Diagnoses (4)
1. Epithelioid mesothelioma, malignant (the primary disease): ICD-O-3 morphology code: 9052/3; ICD-10 code: C45.0; Tissue or organ of origin: Pleura, NOS; Site of resection or biopsy: Pleura, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 64.1 years (23,400 days); Year of diagnosis: 2010; Method of diagnosis: Imaging; AJCC staging edition: 7th; AJCC pathologic T: T4; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R2.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Pemetrexed; Days to treatment start: 25 days; Days to treatment end: 25 days; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 110 days; Days to treatment end: 148 days; Treatment dose: 5,040 cGy; Treatment outcome: Partial Response; Number of fractions: 28; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Everolimus; Days to treatment start: 391 days (1.1 years); Days to treatment end: 543 days (1.5 years); Treatment outcome: Progressive Disease; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Days to treatment start: 564 days (1.5 years); Days to treatment end: 711 days (1.9 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Days to treatment start: 571 days (1.6 years); Days to treatment end: 634 days (1.7 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pemetrexed; Days to treatment start: 739 days (2.0 years); Days to treatment end: 760 days (2.1 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Vinorelbine; Days to treatment start: 790 days (2.2 years); Days to treatment end: 816 days (2.2 years); Treatment outcome: Stable Disease.
   Recorded as not given: Pleurodesis, NOS, prior to procurement.
2. Recurrence of diagnosis 1 (Epithelioid mesothelioma, malignant), site: Thorax, NOS. Age at diagnosis: 65.1 years (23,763 days); Days to diagnosis: 363 days; Prior treatment: Yes.
3. Recurrence of diagnosis 1 (Epithelioid mesothelioma, malignant), site: Thorax, NOS. Age at diagnosis: 65.1 years (23,784 days); Days to diagnosis: 384 days (1.1 years); Prior treatment: Yes.
4. Metastasis of diagnosis 1 (Epithelioid mesothelioma, malignant), site: Thorax, NOS. Age at diagnosis: 66.2 years (24,183 days); Days to diagnosis: 783 days (2.1 years); Prior treatment: Yes.

Follow-up (6 entries)
- Day 363 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Thorax, NOS; Days to recurrence: 363 days.
- Day 384 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Thorax, NOS; Days to recurrence: 384 days (1.1 years).
- Day 783 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Thorax, NOS; Days to progression: 783 days (2.1 years).
- Days to follow up: 881 days (2.4 years); Disease response: With Tumor.
- Karnofsky performance status: 90; ECOG performance status: 0; Timepoint: Preoperative.
- Imaging anatomic site: Pleura; Imaging suv max: 8.3; Timepoint: Prior to Treatment.

Molecular and laboratory tests
- Serum Mesothelin 1.3 nmol/L [Blood test normal range lower: 0; Blood test normal range upper: 1.5].
- Creatinine 0.9 mg/dL [Blood test normal range lower: 0.6; Blood test normal range upper: 1.3].

Exposures
- Exposure type: Asbestos; Exposure source: Secondary.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Mesothelioma.
- Relative with cancer history: yes; Relationship type: Parent; Relationship primary diagnosis: Mesothelioma.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-SC-A6LM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 140 mg.
  Slide TCGA-SC-A6LM-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-SC-A6LM-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-SC-A6LM-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Pleurodesis performed prior: No; Tumor status: With tumor; History asbestos exposure: Yes.
- Primary pathology: Submitted tumor site: Pleura; Histologic diagnosis: Epithelioid mesothelioma; Serum mesothelin prior treatment: 1.3; Mesothelioma detection method: Thorascopy.
- Drug treatment 3: Treatment best response: Clinical Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 881 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 881 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 363 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-SC-A6LM-01A-11D-A34B-01): tumor purity 0.68, ploidy 1.87, whole-genome doublings 0.
